FM case AD2119 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/d4e3ef90-4c1b-4553-85fc-2fd18ca02cb7

Female, 52.0 years: Clear cell carcinoma (ICD-O-3 8310/3) of the ovary; metastasis biopsied or resected from the abdomen. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
